Gene-level copy-number profile of tumor specimen TCGA-85-8071-01A from TCGA case TCGA-85-8071, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.5 years (19,158 days).
Specimen TCGA-85-8071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.bdd84053-6c16-45db-83e3-fd63a5244711.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8071-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cb2a763-2886-46d7-a5ca-3f16b1a359a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 16,585; copy number 2: 39,931; copy number 3: 2,583; copy number 4: 66; copy number 5: 138; copy number 8: 355; copy number 9: 143; copy number 12: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8071-01A-11D-2243-01): tumor purity 0.86, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr9:17,134,982–17,503,923, 2 genes (within-gene range 0–1): CNTLN, SAMM50P1.
- chr14:68,113,706–68,149,908, 3 genes: AL133370.2, AL133370.1, RN7SL706P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 643 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:31,296,982–31,987,034, 25 genes, copy number 5 (within-gene range 3–5): ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1, ADGRB2, MIR4254, AL354919.2, SPOCD1, AL354919.1, AL136115.2, PTP4A2, AL136115.1, AL136115.3.
- chr11:90,085,950–91,872,086, 24 genes, copy number 5: UBTFL1, AP000648.2, AP000648.9, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2, MIR4490, AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756.
- chr13:18,467,172–19,570,288, 47 genes, copy number 8: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1, PSPC1P1, ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2, TPTE2, CYCSP32, MRPS31P2, ESRRAP1.
- chr13:19,563,589–19,564,900, 1 gene, copy number 8: CASC4P1.
- chr14:89,124,871–89,619,149, 1 gene, copy number 12 (within-gene range 3–12): FOXN3.
- chr14:89,349,377–92,907,482, 71 genes, copy number 9–12 (within-gene range 3–12) (broad region; genes not listed).
- chr14:95,047,353–99,332,015, 78 genes, copy number 9 (broad region; genes not listed).
- chr14:103,094,723–106,875,071, 307 genes, copy number 8 (broad region; genes not listed).
- chr18:23,134,564–25,352,190, 48 genes, copy number 5: CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1.
- chr20:35,172,072–35,216,240, 1 gene, copy number 5 (within-gene range 2–5): PROCR.
- chr20:35,195,306–36,030,700, 40 genes, copy number 5: RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P, RNU6-937P, SCAND1, CNBD2.

Autosomal genes at a single copy (total copy number 1): 14,204. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
